Gene-level copy-number profile of tumor specimen TCGA-F4-6460-01A from TCGA case TCGA-F4-6460, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 51.0 years (18,637 days).
Specimen TCGA-F4-6460-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.26a8e4f3-e066-4341-baa3-4b7c5d657b18.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F4-6460-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32f38386-0d73-47c2-ba72-21e63793bbd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,932; copy number 2: 23,296; copy number 3: 21,417; copy number 4: 3,442; copy number 5: 3,849; copy number 6: 1,063; copy number 7: 1,392; copy number 8: 112; copy number 9: 313.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F4-6460-01A-11D-1770-01): tumor purity 0.6, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,978 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–95,683, 1 gene, copy number 5 (within-gene range 3–5): AC093627.1.
- chr7:115,186–33,877,180, 588 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:33,725,981–159,233,377, 2,422 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr16:5,239,802–7,713,340, 1 gene, copy number 6 (within-gene range 2–6): RBFOX1.
- chr16:6,380,476–6,721,960, 4 genes, copy number 6: AC006112.1, AC007223.1, AC007012.2, AC007012.1.
- chr16:6,873,899–9,676,843, 45 genes, copy number 5–6: RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1.
- chr16:9,794,637–9,810,726, 2 genes, copy number 5: AC007218.2, AC007218.3.
- chr16:18,781,295–21,180,616, 71 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–16,053,197, 283 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr20:14,547,184–64,313,132, 1,170 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,928. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
